Somatic mutation profile of tumor specimen TCGA-BP-5194-01A (aliquot TCGA-BP-5194-01A-02D-1429-08) from TCGA case TCGA-BP-5194, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 39.8 years (14,551 days).
Specimen TCGA-BP-5194-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ee35092-b047-4d4f-bea8-ab5ae2b9cb4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5194-11A (Solid Tissue Normal), aliquot TCGA-BP-5194-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef18dd4d-fdf1-4583-aac9-c37003c3ddda

The open-access MAF lists 28 somatic variants for this specimen: 19 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 8, Splice Site 2, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF3 | c.2693C>A p.S898Y | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.94); catalogued as COSV57849450, COSV57864936; called by muse, mutect2, varscan2
- BRPF3 | c.3535G>T p.V1179L | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs752402022, COSV60208830; called by muse, mutect2, varscan2
- C3orf70 | c.285T>G p.I95M | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.134); catalogued as COSV58589603; called by muse, mutect2, varscan2
- COL11A1 | c.1413+1G>T p.X471_splice | Splice Site (SNP) | VAF 66/252 reads (26%) | catalogued as COSV62184963, COSV62190771; called by muse, mutect2, varscan2
- DNAH9 | c.10675A>T p.N3559Y | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52365386; called by muse, mutect2, varscan2
- HEATR5B | c.3559C>T p.H1187Y | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0.039); catalogued as rs1187216693, COSV51856438; called by muse, mutect2, varscan2
- HOXB1 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 81/291 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs753190451, COSV53318201; called by muse, mutect2, varscan2
- KRT2 | c.125G>A p.C42Y | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.242); catalogued as COSV59011858; called by muse, mutect2, varscan2
- LBP | c.508A>G p.M170V | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV54142179; called by muse, mutect2, varscan2
- MAP3K11 | c.740-1G>T p.X247_splice | Splice Site (SNP) | VAF 14/48 reads (29%) | catalogued as COSV58421024; called by muse, mutect2, varscan2
- RALGPS1 | c.811C>A p.L271I | Missense Mutation (SNP) | VAF 17/282 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52228364; called by muse, mutect2
- RGS6 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775343972, COSV59570703; called by muse, mutect2, varscan2
- RNF10 | c.2024G>C p.S675T | Missense Mutation (SNP) | VAF 58/257 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV58047092; called by muse, mutect2, varscan2
- SACS | c.13678G>C p.V4560L | Missense Mutation (SNP) | VAF 9/220 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV66544529; called by muse, mutect2
- TMEM132E | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as rs1183636597, COSV58699267; called by muse, mutect2, varscan2
- VPS35 | c.42G>C p.K14N | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV54480216; called by muse, mutect2, varscan2
- GGA2 | c.1520del p.G507Efs*13 | Frame Shift Del (DEL) | VAF 30/152 reads (20%) | called by mutect2, pindel, varscan2
- GTF2IRD2B | c.2300A>T p.N767I | Missense Mutation (SNP) | VAF 42/223 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PBRM1 | c.343_349del p.D115Sfs*57 | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | called by mutect2, pindel, varscan2
- CCDC148 | c.18T>A p.A6= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV51766964; called by muse, varscan2
- CCDC88C | c.4365C>T p.A1455= | Silent (SNP) | VAF 60/177 reads (34%) | catalogued as rs780519044, COSV58661280; called by muse, varscan2
- CENPF | c.6786G>A p.Q2262= | Silent (SNP) | VAF 38/141 reads (27%) | catalogued as COSV65277345; called by muse, mutect2, varscan2
- CXorf66 | c.168C>T p.I56= | Silent (SNP) | VAF 152/238 reads (64%) | catalogued as COSV65169586; called by muse, varscan2
- POLR2C | c.294G>A p.S98= | Silent (SNP) | VAF 58/174 reads (33%) | catalogued as rs371938475; called by muse, mutect2, varscan2
- SLC28A2 | c.963C>A p.I321= | Silent (SNP) | VAF 98/282 reads (35%) | catalogued as COSV61664798; called by muse, mutect2, varscan2
- SRL | c.333C>T p.N111= | Silent (SNP) | VAF 42/144 reads (29%) | catalogued as COSV68424014; called by muse, mutect2, varscan2
- WEE1 | c.1938C>T p.Y646= | Silent (SNP) | VAF 36/108 reads (33%) | catalogued as COSV55198007; called by muse, mutect2, varscan2
- RBM39 | c.102-2784A>G | Intron (SNP) | VAF 19/47 reads (40%) | catalogued as COSV99488916; called by muse, mutect2, varscan2
